Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LO, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LO-01A (Primary Tumor).

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site: Adrenal Gland Cortex
C74.0

pn 2/6/13

Procedure: Right adrenalectomy

Gross description: tumor is 760g; measuring 13.5 x 9.5 x 6cm.

Diagnosis: Adrenal cortical carcinoma. Weiss score - 7. No extension into liver or kidney. No lymph node mets (+0/19).

Primary Site Discrepancy		
HIS/HA Discrepancy		
Unilateral Synchronous Primary Tumor		

Source: NCI Genomic Data Commons file ecd4515f-6ac5-45cb-b1b5-747b885b114d (TCGA-OR-A5LO.45C2478C-53EF-4422-A9EF-33C40A3AA275.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).